Somatic mutation profile of tumor specimen ALCH-B1TI-TTP1-A (aliquot ALCH-B1TI-TTP1-A-2-0-D-A76B-36) from ALCHEMIST case ALCH-B1TI, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 61.1 years (22,309 days).
Specimen ALCH-B1TI-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 88047ae9-985d-46f7-93fb-645cad3accfa.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1TI-NB1-A (Blood Derived Normal), aliquot ALCH-B1TI-NB1-A-1-0-D-A76B-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0c75a89a-3e76-4a4c-91f0-c406f95fe110

The open-access MAF lists 63 somatic variants for this specimen: 42 protein-altering or splice-affecting, 12 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 40, Silent 12, Intron 3, 5'Flank 2, 3'UTR 1, Nonsense Mutation 1, 5'UTR 1, 3'Flank 1, Splice Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCD2 | c.826C>G p.P276A | Missense Mutation (SNP) | VAF 38/462 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58049664; called by muse, mutect2
- ACOT12 | c.731G>A p.R244H | Missense Mutation (SNP) | VAF 42/573 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.841); catalogued as rs199607014, COSV56896698; called by muse, mutect2
- AVPR1A | c.355G>A p.G119S | Missense Mutation (SNP) | VAF 13/190 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1342372730; called by muse, mutect2
- BTBD11 | c.2053G>A p.E685K (on ENST00000280758 / NM_001018072.2; = p.E222K on NM_001017523.2) | Missense Mutation (SNP) | VAF 38/337 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs760476113, COSV55022926; called by muse, mutect2, varscan2
- CHST1 | c.256G>A p.V86I | Missense Mutation (SNP) | VAF 18/171 reads (11%) | SIFT tolerated (0.93); PolyPhen benign (0.021); catalogued as COSV57326146; called by muse, mutect2, varscan2
- CLRN2 | c.577G>A p.V193M | Missense Mutation (SNP) | VAF 56/496 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as rs929818039; called by muse, mutect2, varscan2
- DBX2 | c.449C>T p.A150V | Missense Mutation (SNP) | VAF 30/268 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.078); catalogued as rs377142325, COSV100224268; called by muse, mutect2, varscan2
- FBXW7 | c.1675C>G p.L559V (on ENST00000281708 / NM_001349798.2; = p.L479V on NM_018315.5) | Missense Mutation (SNP) | VAF 49/374 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV55945819; called by muse, mutect2, varscan2
- GSDMA | c.985G>A p.V329M | Missense Mutation (SNP) | VAF 46/363 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as rs754738073, COSV100053897; called by muse, mutect2, varscan2
- IGHV1-3 | c.181G>A p.G61R | Missense Mutation (SNP) | VAF 51/496 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.797); catalogued as rs782350057; called by muse, mutect2, varscan2
- ISX | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 23/451 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as rs753099390, COSV58088734; called by muse, mutect2
- PLA2G4E | c.472A>G p.T158A | Missense Mutation (SNP) | VAF 22/236 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1301216897, COSV68150709; called by muse, mutect2
- PPP1R9A | c.2696C>T p.S899F | Missense Mutation (SNP) | VAF 34/423 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.613); catalogued as COSV56885233; called by muse, mutect2
- SCNN1A | c.1310C>T p.P437L | Missense Mutation (SNP) | VAF 34/356 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs571384931; called by muse, mutect2
- SGIP1 | c.1870G>A p.V624I | Missense Mutation (SNP) | VAF 39/287 reads (14%) | SIFT tolerated (0.52); PolyPhen benign (0.275); catalogued as rs758255665; called by muse, mutect2, varscan2
- SLC22A16 | c.1475C>T p.A492V | Missense Mutation (SNP) | VAF 35/368 reads (10%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.826); catalogued as rs368955884; called by muse, mutect2
- THOP1 | c.929G>A p.R310H | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.969); catalogued as rs370445695; called by muse, mutect2
- UNC5D | c.2412C>A p.C804* | Nonsense Mutation (SNP) | VAF 20/262 reads (8%) | catalogued as rs1334945488; called by muse, mutect2
- BOD1L1 | c.7843G>T p.D2615Y | Missense Mutation (SNP) | VAF 20/286 reads (7%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.015); called by muse, mutect2
- CACNG3 | c.29T>A p.M10K | Missense Mutation (SNP) | VAF 34/431 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2
- CDH9 | c.493A>C p.T165P | Missense Mutation (SNP) | VAF 12/216 reads (6%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.653); called by muse, mutect2
- CLMN | c.1018C>T p.H340Y | Missense Mutation (SNP) | VAF 32/394 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.337); called by muse, mutect2
- COL22A1 | c.2359G>C p.E787Q | Missense Mutation (SNP) | VAF 18/282 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.79); called by muse, mutect2
- DPY19L2 | c.1132A>T p.I378F | Missense Mutation (SNP) | VAF 20/222 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.232); called by muse, mutect2
- DPY19L2 | c.1132-1G>C p.X378_splice | Splice Site (SNP) | VAF 18/216 reads (8%) | called by muse, mutect2
- FAM178B | c.674G>A p.C225Y | Missense Mutation (SNP) | VAF 19/258 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- FAM78B | c.226C>A p.Q76K | Missense Mutation (SNP) | VAF 33/385 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.025); called by muse, mutect2
- FAT1 | c.13627A>T p.T4543S | Missense Mutation (SNP) | VAF 37/404 reads (9%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.556); called by muse, mutect2
- FLNA | c.5081C>T p.S1694L (on ENST00000369850 / NM_001110556.2; = p.S1686L on NM_001456.3) | Missense Mutation (SNP) | VAF 32/264 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- GBA | c.1315A>C p.S439R | Missense Mutation (SNP) | VAF 40/532 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KCTD11 | c.295G>A p.E99K (on ENST00000333751 / NM_001363642.1; = p.E60K on NM_001002914.2) | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- KLHL9 | c.1262C>G p.P421R | Missense Mutation (SNP) | VAF 55/437 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- MAP3K4 | c.1162G>C p.D388H | Missense Mutation (SNP) | VAF 15/204 reads (7%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.885); called by muse, mutect2
- PALMD | c.1072C>A p.Q358K | Missense Mutation (SNP) | VAF 14/332 reads (4%) | SIFT tolerated (0.49); PolyPhen benign (0.251); called by muse, mutect2
- PHKA1 | c.2471G>A p.G824D | Missense Mutation (SNP) | VAF 56/454 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- POM121L2 | c.2648G>A p.S883N | Missense Mutation (SNP) | VAF 27/258 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.51); called by mutect2, varscan2
- POTEJ | c.259G>A p.D87N | Missense Mutation (SNP) | VAF 14/118 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.141); called by mutect2, varscan2
- PPP1R37 | c.460C>G p.L154V | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.311); called by muse, varscan2
- RAB4A | c.212G>A p.G71E | Missense Mutation (SNP) | VAF 28/288 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); called by muse, mutect2
- THBD | c.877G>A p.E293K | Missense Mutation (SNP) | VAF 13/134 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- TRIM23 | c.454C>A p.Q152K | Missense Mutation (SNP) | VAF 36/370 reads (10%) | SIFT tolerated (0.44); PolyPhen benign (0.222); called by muse, mutect2
- ZNF442 | c.1111C>T p.H371Y | Missense Mutation (SNP) | VAF 46/436 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ATG2A | c.3402C>T p.I1134= | Silent (SNP) | VAF 14/354 reads (4%) | catalogued as rs868004121; called by muse, mutect2
- CRYGC | c.315G>C p.L105= | Silent (SNP) | VAF 21/388 reads (5%) | catalogued as rs1222279077; called by muse, mutect2
- FBXW9 | c.238C>T p.L80= | Silent (SNP) | VAF 22/251 reads (9%) | catalogued as COSV63510295; called by muse, mutect2
- IKBKG | c.45G>A p.V15= | Silent (SNP) | VAF 34/316 reads (11%) | called by muse, mutect2, varscan2
- IL5 | c.132G>A p.L44= | Silent (SNP) | VAF 9/188 reads (5%) | called by muse, mutect2
- LAMB4 | c.1644G>A p.L548= | Silent (SNP) | VAF 32/252 reads (13%) | called by muse, mutect2, varscan2
- PPARGC1A | c.1467C>T p.F489= | Silent (SNP) | VAF 19/229 reads (8%) | catalogued as COSV99338458; called by muse, mutect2
- PTPDC1 | c.1620G>A p.Q540= (on ENST00000375360 / NM_177995.3; = p.Q592= on NM_152422.4) | Silent (SNP) | VAF 27/229 reads (12%) | called by muse, mutect2, varscan2
- SOD3 | c.453C>T p.V151= | Silent (SNP) | VAF 28/334 reads (8%) | called by muse, mutect2
- SPG7 | c.1776G>A p.R592= (on ENST00000268704; = p.R599= on NM_003119.4) | Silent (SNP) | VAF 54/509 reads (11%) | called by muse, mutect2, varscan2
- SRSF6 | c.66C>T p.F22= | Silent (SNP) | VAF 24/181 reads (13%) | catalogued as rs749027915; called by muse, mutect2, varscan2
- XYLT1 | c.1464C>A p.A488= | Silent (SNP) | VAF 31/306 reads (10%) | called by muse, mutect2, varscan2
- ACSL5 | c.-157G>A | 5'UTR (SNP) | VAF 21/202 reads (10%) | called by muse, mutect2, varscan2
- CDKL1 | c.367-708G>A | Intron (SNP) | VAF 22/163 reads (13%) | called by muse, mutect2, varscan2
- EFHC1 | c.*2077C>T | 3'UTR (SNP) | VAF 51/407 reads (13%) | called by muse, mutect2, varscan2
- FAM90A27P | n.1018C>T | RNA (SNP) | VAF 25/333 reads (8%) | catalogued as rs755831312; called by muse, mutect2
- MAFG | c.37-37G>T | Intron (SNP) | VAF 10/118 reads (8%) | called by muse, mutect2
- MIR6080 | chr17:64780132 G>A | 5'Flank (SNP) | VAF 36/271 reads (13%) | called by muse, mutect2, varscan2
- SKOR1 | chr15:67825014 G>T | 5'Flank (SNP) | VAF 8/118 reads (7%) | called by muse, mutect2
- TRIM61 | c.526-2156G>A | Intron (SNP) | VAF 37/308 reads (12%) | catalogued as COSV100256267; called by muse, mutect2, varscan2
- TUT1 | chr11:62574766 G>A | 3'Flank (SNP) | VAF 50/507 reads (10%) | called by muse, mutect2, varscan2
